Gene-level copy-number profile of specimen HCM-SANG-0303-C15-85A from HCMI case HCM-SANG-0303-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0303-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 87d95579-399f-46a3-a95a-dc20e908f430.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0303-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/eaf1004d-d4e2-4b1d-9e3b-44dbc9eb4560

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 336; copy number 2: 33,127; copy number 3: 13,832; copy number 4: 9,281; copy number 5: 924; copy number 6: 14; copy number 7: 741; copy number 8: 137; copy number 10: 2; copy number 11: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,319,034–91,325,306, 1 gene (within-gene range 0–2): AC074124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,064 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 2 genes, copy number 5 (within-gene range 2–5): AL627309.1, AL627309.3.
- chr2:89,252,211–89,600,680, 11 genes, copy number 5: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:89,947,512–90,190,681, 22 genes, copy number 6–7: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42.
- chr3:41,162,287–41,962,130, 5 genes, copy number 10–11 (within-gene range 2–11): AC009743.1, MRPS31P1, CTNNB1, ULK4, AC099537.1.
- chr10:31,206,278–31,320,447, 1 gene, copy number 5 (within-gene range 4–5): ZEB1-AS1.
- chr10:31,318,495–33,917,804, 44 genes, copy number 5: ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.
- chr10:34,815,767–38,783,108, 84 genes, copy number 5 (broad region; genes not listed).
- chr19:48,793,152–49,036,895, 25 genes, copy number 5 (within-gene range 4–5): RNU6-317P, BCAT2, AC026803.3, HSD17B14, PLEKHA4, PPP1R15A, TULP2, NUCB1, NUCB1-AS1, AC026803.1, DHDH, BAX, AC026803.2, FTL, GYS1, RUVBL2, MIR6798, LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1.
- chr20:30,214,765–64,327,972, 870 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
